Somatic mutation profile of tumor specimen MP2PRT-PAPENK-TMP1-A (aliquot MP2PRT-PAPENK-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPENK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,701 days).
Specimen MP2PRT-PAPENK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b428e078-2e69-4a1d-a30c-7d5bd9ea71d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPENK-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPENK-NM1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41a1d10c-fb0f-46c6-a022-1103dbcc73fc

The open-access MAF lists 28 somatic variants for this specimen: 25 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 20, Silent 3, Frame Shift Ins 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HPS4 | c.57del p.L20Ffs*7 | Frame Shift Del (DEL) | VAF 86/317 reads (27%) | catalogued as rs281865097, CD020569; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTPN11 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 131/348 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1323696380; called by muse, varscan2
- ADGRF1 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 80/258 reads (31%) | catalogued as rs761959982, CM157802; called by muse, mutect2, varscan2
- DNAH9 | c.3473G>A p.R1158Q | Missense Mutation (SNP) | VAF 131/423 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs771170445, COSV52367390; called by muse, mutect2, varscan2
- EIF5 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 128/376 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV53686225; called by muse, mutect2, varscan2
- GIMAP7 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs761959705, COSV57958744, COSV57960327; called by muse, mutect2, varscan2
- ITSN1 | c.3991C>T p.R1331C | Missense Mutation (SNP) | VAF 150/650 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV67157070; called by muse, mutect2, varscan2
- KRT84 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs748157753; called by muse, mutect2, varscan2
- MGAM | c.2207C>T p.T736M | Missense Mutation (SNP) | VAF 101/237 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199856344; called by muse, mutect2, varscan2
- MYH14 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 143/318 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as rs763292852, COSV99223108; called by muse, mutect2, varscan2
- OR5H6 | c.752G>A p.R251Q (on ENST00000642105; = p.R235Q on NM_001005479.2) | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.248); catalogued as rs145676438; called by muse, mutect2
- PRR30 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 172/530 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs550970267, COSV99574556; called by muse, mutect2, varscan2
- PTCHD4 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 122/410 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.413); catalogued as rs1401420321, COSV59791683; called by muse, mutect2, varscan2
- SCLY | c.1138G>A p.V380M (on ENST00000651534; = p.V372M on NM_016510.7) | Missense Mutation (SNP) | VAF 164/567 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs991227242; called by muse, mutect2, varscan2
- ATP8B4 | c.2910C>A p.F970L | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BX276092.9 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 168/636 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ETV6 | c.141_142insTT p.I48Lfs*20 | Frame Shift Ins (INS) | VAF 124/312 reads (40%) | called by mutect2, pindel, varscan2
- LAMA2 | c.1213C>G p.P405A | Missense Mutation (SNP) | VAF 9/292 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.114); called by muse, mutect2
- MEOX2 | c.891C>A p.H297Q | Missense Mutation (SNP) | VAF 100/233 reads (43%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5V1 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 127/458 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PCDHB3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 93/373 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- PHYHIP | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 26/552 reads (5%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); called by muse, mutect2
- TM7SF3 | c.1088dup p.A364Sfs*41 | Frame Shift Ins (INS) | VAF 164/416 reads (39%) | called by mutect2, pindel, varscan2
- XBP1 | c.555dup p.I186Hfs*201 | Frame Shift Ins (INS) | VAF 103/463 reads (22%) | called by mutect2, pindel, varscan2
- BAIAP2 | c.114C>T p.Y38= | Silent (SNP) | VAF 85/422 reads (20%) | catalogued as rs773315608; called by muse, mutect2, varscan2
- PSD | c.1356G>A p.R452= | Silent (SNP) | VAF 115/521 reads (22%) | called by muse, mutect2, varscan2
- ZNF843 | c.822C>T p.S274= | Silent (SNP) | VAF 34/653 reads (5%) | catalogued as rs1049468913, COSV59847681; called by muse, mutect2
